Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A7SQ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A7SQ-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site @ Kidney NOS C64.9
JW 10/4/13

Surgical Pathology Report

Final

Surgical Pathology Report

Clinic Number: Name:

Requested By:

DIAGNOSIS:

Kidney, left, nephrectomy:

Two tumors identified.

Tumor #1

Histologic type: Papillary renal cell carcinoma (see comment).

Histologic Fuhrman grade: Grade 2/4.

Tumor size: 3.5 x 3.0 x 2.5 cm.

Tumor site: Lower pole.

Tumor focality: Not applicable.

Sarcomatoid features: Absent.

Tumor necrosis: Absent.

Microscopic tumor extension: The tumor extends into the renal sinus.

Margins: Not involved.

Lymphovascular invasion: Absent.

Lymph nodes: No lymph nodes found in hilar fat.

DIAGNOSIS COMMENT:

Immunostains in tumor #1 showed:

[page 2 of 3]
racemase: positive
CK7: positive
C-Kit: negative.
CD10: only rare positivity.
The results are those typically reported in papillary renal cell carcinoma.

CLINICAL INFORMATION:

Left renal mass.

SPECIMEN(S):

A: Left kidney

PRELIMINARY INTRAOPERATIVE DIAGNOSIS:

Intraoperative Pathologist(s):

A. Left kidney, frozen section diagnosis: Renal cell carcinoma.
Tissue sent for

GROSS DESCRIPTION:

Performed by

A. Received fresh labels and "left kidney."

Procedure: Radical nephrectomy.

Specimen laterality: Left.

Tumor site: Lower pole and a second tumor upper pole inferior.

Tumor size: Lower pole tumor: 3.5 x 3 x 2.5 cm. Upper pole tumor: 1.8 x 1.5 x 1.5 cm.

Tumor focality: Multifocal.

Gross extent of tumor:

Extension into perinephric tissue: Present. The tumor in the lower pole abuts the renal sinus and perinephric tissue.

Extension beyond Gerota's fascia: Absent.

Extension into renal sinus: Absent.

Extension into collecting system: Absent.

Adrenal gland: Adrenal gland absent.

Gross notes:

Gross tumor characteristics: The tumor #1 in the lower pole is necrotic and somewhat papular. Tumor #2 in the upper pole is well-circumscribed and yellow-orange with focal necrosis.

Kidney weight: 478 g with fat and 184 g without fat.

Kidney dimensions: 10.5 x 6 x 5.2 cm.

Ureter dimensions: 6 x 0.4 x 0.3 cm.

Lymph nodes: Absent.

Inking details: The perinephric fat is inked over the mass in the lower pole.

Block summary for specimen A,

A1) Frozen section - tumor; A2) ureteral and vascular margins;

A3-A4) sections of tumor #1 in lower pole; A5) fat in capsule over lower pole tumor; A6-A7) sections of upper pole tumor; A8) section of lower pole tumor abutting renal sinus.

[page 3 of 3]
Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ('CLIA') as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file f49a2fda-cca7-493f-b912-991cd1f72950 (TCGA-SX-A7SQ.BFAB9079-A4A6-457C-8CF5-3D8BB15FEB4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).